Somatic mutation profile of tumor specimen MP2PRT-PAVUZU-TMP1-A (aliquot MP2PRT-PAVUZU-TMP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAVUZU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,567 days).
Specimen MP2PRT-PAVUZU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e6802e3-db46-4bce-9e01-a9db8743bffb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUZU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUZU-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2b7e15a-3186-46e2-b1f9-a38ceea568ca

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS9 | c.4549G>A p.V1517I | Missense Mutation (SNP) | VAF 133/316 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.021); catalogued as rs868532784, COSV55792269; called by muse, mutect2, varscan2
- EGFR | c.3405C>A p.N1135K | Missense Mutation (SNP) | VAF 225/371 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as rs765499904; called by muse, mutect2, varscan2
- EPHA10 | c.2669G>A p.R890Q | Missense Mutation (SNP) | VAF 209/596 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs756079971, COSV57627500; called by muse, mutect2, varscan2
- TBCD | c.1851G>A p.M617I | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs765676190; called by muse, mutect2, varscan2
- VWA8 | c.4115G>A p.G1372D | Missense Mutation (SNP) | VAF 82/245 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1331414796; called by muse, mutect2, varscan2
- ASIC5 | c.895A>T p.N299Y | Missense Mutation (SNP) | VAF 169/423 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLC16A2 | c.872C>G p.P291R | Missense Mutation (SNP) | VAF 238/704 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRRX2 | c.402C>T p.R134= | Silent (SNP) | VAF 192/494 reads (39%) | catalogued as rs749511698, COSV65242977; called by muse, varscan2
- SH2D4A | c.42T>C p.D14= | Silent (SNP) | VAF 139/353 reads (39%) | called by muse, mutect2, varscan2
